CCDI case PBBNIR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/009a6a80-ed69-4904-91b9-b0465ee15447

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.7 years (244 days).

Biospecimens (3 samples)
- Sample 0DD86X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DD871: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DD873: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
